Gene-level copy-number profile of tumor specimen TCGA-58-A46J-01A from TCGA case TCGA-58-A46J, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.8 years (23,653 days).
Specimen TCGA-58-A46J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.783c3554-c655-4093-aee9-3e960ec9a9b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-A46J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2944abdd-f3cb-46c6-9bd7-5bf07fad58c2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 16,057; copy number 3: 11,705; copy number 4: 26,736; copy number 5: 254; copy number 6: 1,257; copy number 7: 2,748; copy number 8: 798; copy number 9: 139; copy number 11: 11; copy number 13: 98; copy number 19: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-A46J-01A-11D-A24C-01): tumor purity 0.51, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 260 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,425,850–172,604,006, 6 genes, copy number 11: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr9:38,360,427–43,045,120, 139 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr15:97,876,289–101,933,350, 110 genes, copy number 13–19 (broad region; genes not listed).
- chr18:832,238–912,172, 5 genes, copy number 11: BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
